Somatic mutation profile of tumor specimen TCGA-L5-A8NG-01A (aliquot TCGA-L5-A8NG-01A-11D-A37C-09) from TCGA case TCGA-L5-A8NG, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 77.3 years (28,219 days).
Specimen TCGA-L5-A8NG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 762919df-2135-47ac-8bfe-205f8bedf471.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NG-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NG-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28847f24-f6a8-484a-bd01-974010ab977b

The open-access MAF lists 149 somatic variants for this specimen: 107 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 37, Nonsense Mutation 4, Frame Shift Del 3, Intron 2, Splice Site 1, 3'UTR 1, In Frame Del 1, RNA 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AGL | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV54055862; called by muse, mutect2, varscan2
- ALPP | c.194-1G>A p.X65_splice | Splice Site (SNP) | VAF 7/35 reads (20%) | catalogued as rs775948634; called by muse, mutect2, varscan2
- ANKRD30A | c.608A>C p.K203T (on ENST00000611781; = p.K147T on NM_052997.2) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.171); catalogued as COSV64604232, COSV64607964; called by muse, mutect2, varscan2
- ARMC4 | c.2654T>C p.L885P | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV59460358; called by muse, mutect2, varscan2
- CDKN2A | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.02); catalogued as rs45476696, CM1414341, CM156717, CS108038, CS972842, COSV58690140, COSV58729212; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.874T>G p.F292V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV70488253; called by muse, mutect2, varscan2
- CPQ | c.308T>G p.V103G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55149087; called by muse, mutect2, varscan2
- CTSO | c.877A>G p.S293G | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.309); catalogued as COSV70808893, COSV70809027; called by muse, mutect2, varscan2
- DLGAP2 | c.2210C>T p.T737M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs973854776; called by muse, mutect2, varscan2
- DNAI1 | c.661T>G p.F221V | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as COSV54279485, COSV54279893; called by muse, mutect2
- DOCK2 | c.3173A>C p.K1058T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56963361, COSV56971995; called by muse, mutect2, varscan2
- DPP10 | c.2094A>C p.E698D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0.013); catalogued as COSV100065107, COSV100070166; called by muse, mutect2, varscan2
- DTWD1 | c.203A>C p.Y68S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52073137; called by muse, mutect2, varscan2
- DYNC2I2 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs747197509, COSV65549254; called by muse, mutect2, varscan2
- FGF13 | c.128A>C p.K43T | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs1287704472; called by muse, mutect2, varscan2
- GREB1 | c.4299G>T p.K1433N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99029496; called by muse, mutect2, varscan2
- H3C3 | c.331_332del p.C111Rfs*5 | Frame Shift Del (DEL) | VAF 28/47 reads (60%) | catalogued as rs761955716; called by pindel, varscan2
- HAP1 | c.1021C>G p.L341V | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs1555590887; called by muse, mutect2, varscan2
- HMCN1 | c.662T>G p.V221G | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54953884, COSV99634592; called by muse, mutect2, varscan2
- HRH3 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs1163249261; called by muse, mutect2, varscan2
- HSF2 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs1299289284; called by muse, mutect2, varscan2
- IL12RB1 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.267); catalogued as rs1357460137; called by muse, mutect2, varscan2
- INPP4A | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs776893699; called by mutect2, varscan2
- KCNG2 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.063); catalogued as rs766009096; called by muse, mutect2, varscan2
- KMT2C | c.12274G>T p.E4092* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV51437744; called by muse, mutect2, varscan2
- KRTAP10-9 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV59982577; called by muse, mutect2
- LCN9 | c.487T>C p.S163P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.127); catalogued as rs1477419156; called by muse, mutect2, varscan2
- LCP2 | c.200A>C p.K67T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50447085; called by muse, mutect2, varscan2
- LRP2 | c.8947G>A p.D2983N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051877373; called by muse, mutect2, varscan2
- MOCS3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as rs771185327; called by muse, varscan2
- NCKAP5 | c.4096A>G p.S1366G | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs757356901, COSV58445055; called by muse, mutect2, varscan2
- NEGR1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1248852117, COSV100165398, COSV60868612, COSV60871717; called by muse, mutect2, varscan2
- OR2T33 | c.86T>A p.V29D | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV58815988; called by muse, varscan2
- P2RY8 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs762114324, COSV67177276; called by muse, mutect2, varscan2
- RANBP17 | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.112); catalogued as COSV66652798; called by muse, mutect2, varscan2
- RET | c.2544G>C p.M848I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.592); catalogued as COSV60708060; called by mutect2, varscan2
- SPTA1 | c.6817C>G p.L2273V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV63754212, COSV63759561; called by muse, mutect2, varscan2
- SULF1 | c.34G>T p.V12F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV52677172; called by muse, mutect2
- TLL2 | c.2962C>T p.R988C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs191958370, COSV100780501, COSV63570836; called by mutect2, varscan2
- TMPRSS15 | c.2054C>T p.T685M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs750285967, COSV53034292, COSV53035773; called by muse, mutect2, varscan2
- TTC1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as rs772486884; called by mutect2, varscan2
- WDR62 | c.1009C>G p.L337V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV54336469; called by muse, mutect2, varscan2
- ZFYVE21 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs758635063, COSV53695700; called by mutect2, varscan2
- ABCB9 | c.759A>G p.I253M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- AFF2 | c.2615A>T p.E872V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- AGPS | c.412G>C p.V138L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AHNAK2 | c.12869A>C p.D4290A | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- ASXL2 | c.28_29del p.G10Qfs*22 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel*
- ATP10A | c.1980G>T p.Q660H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- BCCIP | c.943_*2dup | Nonsense Mutation (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel
- BDNF | c.613A>C p.N205H | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- C2orf69 | c.612G>C p.K204N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.129); called by muse, mutect2
- CACNA1G | c.5299G>A p.D1767N | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CACNA2D1 | c.2641A>T p.S881C (on ENST00000356253 / NM_001366867.1; = p.S869C on NM_000722.4) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMTA1 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- CAPN9 | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- CES1 | c.692T>G p.V231G | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CHD3 | c.571G>C p.A191P | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CYP2C18 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, varscan2
- ERICH3 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FDXR | c.96C>A p.F32L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GALNT17 | c.1318A>C p.S440R | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRK3 | c.674A>C p.K225T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by mutect2, varscan2
- IGHMBP2 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- IGKV3D-20 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- INSR | c.1558T>C p.W520R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- IQCD | c.330G>C p.E110D | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- KCNT2 | c.3341A>T p.E1114V | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KDM6A | c.3176A>T p.D1059V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- KIAA1755 | c.3047_3051del p.A1016Gfs*25 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- KLK15 | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by muse, mutect2
- KPRP | c.568A>G p.S190G | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- LRRC37A2 | c.3566G>T p.R1189M | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, varscan2
- MAGEE2 | c.885A>C p.K295N | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MAOB | c.65T>G p.L22R | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MFAP3L | c.620G>T p.R207L | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MUC6 | c.316_318del p.V106del | In Frame Del (DEL) | VAF 10/36 reads (28%) | called by pindel, varscan2
- MYEF2 | c.1663A>C p.K555Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- NCOA2 | c.2869C>T p.Q957* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- NELL1 | c.630C>G p.I210M | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2
- NEUROD4 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- NLRP14 | c.2230A>C p.N744H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.776); called by muse, mutect2
- NUTM2G | c.1280G>C p.S427T | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- OR4B1 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- OR4C16 | c.852T>G p.I284M | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PAFAH1B3 | c.119A>C p.E40A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- PAPPA2 | c.2999A>G p.D1000G | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PDE7A | c.1352G>A p.W451* (on ENST00000401827 / NM_001242318.3; = p.W425* on NM_002603.4) | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- PRAMEF14 | c.820A>C p.I274L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRN2 | c.784A>G p.S262G | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- QRFPR | c.1124A>C p.K375T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- RUSC1 | c.197G>T p.S66I | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- SEMA6D | c.550T>C p.Y184H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC39A12 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SMARCA1 | c.1180T>G p.F394V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SND1 | c.2437G>A p.A813T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SPG11 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- SUPT20HL2 | c.680A>T p.K227M | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- SUPT6H | c.4673A>C p.N1558T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- THRA | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.01); called by muse, varscan2
- TUBA3C | c.1181A>C p.K394T | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TWIST1 | c.500A>C p.E167A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- VPS26A | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); called by mutect2, varscan2
- ZFP82 | c.1487A>C p.H496P | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFPM2 | c.422A>C p.K141T | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ZNF675 | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- AC005833.1 | c.1089C>T p.A363= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs766264335; called by muse, mutect2
- ACHE | c.1212G>A p.L404= | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- ACTL6B | c.81C>T p.Y27= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV50514988; called by muse, mutect2
- ACTRT3 | c.1118G>A p.*373= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- ADRM1 | c.552G>A p.G184= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as rs1413537549; called by muse, mutect2
- AHNAK | c.8607T>A p.V2869= | Silent (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- APLF | c.999C>T p.G333= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs762165483, COSV58143106; called by muse, mutect2, varscan2
- ATP4A | c.1122G>A p.A374= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99382678; called by muse, mutect2, varscan2
- BICC1 | c.2029T>C p.L677= | Silent (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- CCDC180 | c.765A>G p.E255= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- CNTN6 | c.2445T>C p.S815= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV63167623; called by mutect2, varscan2
- DCDC1 | c.849T>A p.S283= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- EYS | c.762A>G p.S254= | Silent (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- FPGS | c.339C>T p.F113= | Silent (SNP) | VAF 4/44 reads (9%) | called by mutect2, varscan2
- GPR83 | c.1206C>T p.P402= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- GRID1 | c.2118T>G p.A706= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- KIAA0319 | c.2205C>T p.S735= | Silent (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- MAGED1 | c.2202C>T p.F734= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as rs1249123674, COSV58514754; called by muse, mutect2, varscan2
- MKI67 | c.5634G>A p.K1878= | Silent (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- MYO15A | c.684C>T p.G228= | Silent (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- MYO5B | c.735G>A p.E245= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- OR10Q1 | c.426C>T p.R142= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV57469838; called by muse, mutect2
- OR2M5 | c.417A>G p.K139= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV63546847; called by muse, mutect2, varscan2
- PARP10 | c.69C>G p.P23= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as rs782276875, COSV100477788, COSV100478013; called by muse, mutect2, varscan2
- PCDHAC1 | c.66C>T p.L22= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs782614627; called by muse, mutect2, varscan2
- PCLO | c.3615T>G p.A1205= | Silent (SNP) | VAF 15/66 reads (23%) | called by muse, mutect2, varscan2
- PDHA2 | c.630T>C p.A210= | Silent (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2, varscan2
- PRAMEF5 | c.439T>C p.L147= | Silent (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- RAP1GDS1 | c.1386G>A p.V462= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- RAX | c.351C>T p.V117= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV56873987; called by muse, mutect2, varscan2
- RIMS1 | c.2913T>C p.N971= | Silent (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- SEC14L5 | c.315C>T p.R105= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV52042852; called by mutect2, varscan2
- SYT5 | c.558G>T p.L186= | Silent (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- TFR2 | c.264G>A p.T88= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs747341157; called by mutect2, varscan2
- TRPA1 | c.1563G>T p.A521= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs369662285; called by muse, mutect2, varscan2
- TTC3 | c.246C>T p.C82= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs757510843, COSV61286759; called by muse, mutect2, varscan2
- ZNF254 | c.1878A>G p.G626= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73847502 G>A | 5'Flank (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- C14orf177 | n.747A>C | RNA (SNP) | VAF 10/34 reads (29%) | catalogued as COSV57902046; called by muse, mutect2, varscan2
- EPHA6 | c.2784+10229A>C | Intron (SNP) | VAF 4/17 reads (24%) | catalogued as COSV101065416; called by muse, mutect2, varscan2
- NACA | c.71-4108C>G | Intron (SNP) | VAF 5/48 reads (10%) | catalogued as rs1565896482; called by muse, mutect2, varscan2
- TRIM8 | c.*263G>A | 3'UTR (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
